Somatic mutation profile of tumor specimen TARGET-10-PARNJB-09A (aliquot TARGET-10-PARNJB-09A-01D) from TARGET case TARGET-10-PARNJB, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 22.5 years (8,232 days).
Specimen TARGET-10-PARNJB-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea5e020f-3edd-4c34-92ec-4eb80fa4036a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARNJB-10A (Blood Derived Normal), aliquot TARGET-10-PARNJB-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d6645004-b37f-4c8d-930c-1ad943742876

The open-access MAF lists 27 somatic variants for this specimen: 23 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Nonsense Mutation 3, Silent 2, Frame Shift Ins 2, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 60/150 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- WT1 | c.1069C>T p.R357* | Nonsense Mutation (SNP) | VAF 35/70 reads (50%) | catalogued as rs1423753702, CM971594, COSV60067818, COSV60068249, COSV60071382, COSV60073329, COSV60074859, COSV60075137; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAM11 | c.1793G>A p.C598Y | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52349169; called by muse, mutect2, varscan2
- ADAP1 | c.499G>T p.D167Y | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99763406; called by muse, mutect2
- DNAJC28 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758184907, COSV58722065; called by muse, varscan2
- EPHB3 | c.2105C>T p.T702I | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57808539; called by muse, mutect2, varscan2
- GATA3 | c.1039C>G p.L347V | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60520634, COSV60522543; called by muse, mutect2, varscan2
- GPD2 | c.1781C>T p.T594I | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs371726623, COSV60095821; called by muse, mutect2, varscan2
- L3MBTL1 | c.1048G>A p.V350M (on ENST00000418998 / NM_001377303.1; = p.V260M on NM_015478.7) | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753126855, COSV64229407; called by muse, mutect2, varscan2
- MED12 | c.103G>T p.E35* | Nonsense Mutation (SNP) | VAF 57/108 reads (53%) | catalogued as COSV61344550, COSV61352035; called by muse, mutect2, varscan2
- MTG2 | c.1123G>A p.G375S | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.481); catalogued as rs368976452; called by muse, mutect2, varscan2
- MYO1D | c.2081G>A p.R694H | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs371286076, COSV100553762; called by muse, varscan2
- NOTCH1 | c.5039T>C p.I1680T | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV53025693, COSV53032125, COSV53096766; called by muse, mutect2, varscan2
- SBF2 | c.4123A>G p.K1375E | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.65); catalogued as rs1217139040, COSV56306049; called by mutect2, varscan2
- SLC19A3 | c.905T>C p.L302P | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51454393; called by muse, mutect2, varscan2
- STRN4 | c.904G>T p.E302* | Nonsense Mutation (SNP) | VAF 4/31 reads (13%) | catalogued as COSV54416252; called by muse, varscan2
- TTN | c.27142C>T p.R9048W (on ENST00000591111; = p.R8121W on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/36 reads (36%) | PolyPhen benign (0.007); catalogued as rs190600127, COSV60269236; ClinVar: uncertain significance; called by muse, mutect2
- UVSSA | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as rs781746901, COSV66230681; called by muse, mutect2, varscan2
- CYRIA | c.622G>T p.V208F | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.443); called by muse, mutect2
- GPRC5B | c.786G>T p.Q262H | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2
- NOTCH1 | c.7072_7073dup p.L2359Pfs*5 | Frame Shift Ins (INS) | VAF 10/22 reads (45%) | called by mutect2, varscan2
- NUP205 | c.1453C>A p.Q485K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.089); called by muse, mutect2
- WT1 | c.880dup p.Y294Lfs*4 | Frame Shift Ins (INS) | VAF 19/37 reads (51%) | called by mutect2, pindel, varscan2
- PIGN | c.6G>T p.L2= | Silent (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- WNT3A | c.468C>T p.S156= | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as rs1467269448; called by mutect2, varscan2
- LETM2 | c.645+2843C>T | Intron (SNP) | VAF 8/16 reads (50%) | called by muse, mutect2, varscan2
- OR2A13P | n.817C>T | RNA (SNP) | VAF 42/103 reads (41%) | catalogued as rs762934736; called by muse, mutect2, varscan2
